Somatic mutation profile of tumor specimen TCGA-C5-A901-01A (aliquot TCGA-C5-A901-01A-11D-A37N-09) from TCGA case TCGA-C5-A901, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G2; Age at diagnosis: 44.3 years (16,186 days).
Specimen TCGA-C5-A901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 859c0813-eab6-4119-b795-1e7b8eeaf94a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A901-10A (Blood Derived Normal), aliquot TCGA-C5-A901-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bda4b38-e7dd-4a01-8a23-a1f5d3f39048

The open-access MAF lists 103 somatic variants for this specimen: 67 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 33, Nonsense Mutation 5, Splice Site 4, Intron 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC4 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.307); catalogued as COSV59546104; called by muse, mutect2, varscan2
- AQP2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs1229039151, COSV99550953; called by muse, mutect2, varscan2
- ASXL1 | c.2803C>G p.P935A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.028); catalogued as COSV100041196, COSV60107705; called by muse, mutect2, varscan2
- C1RL | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1565636073, COSV99864950; called by muse, mutect2, varscan2
- CACNA1E | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV62426629; called by muse, mutect2, varscan2
- CDC42EP4 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.321); catalogued as COSV59963767; called by muse, mutect2, varscan2
- CDH11 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV51768834, COSV99219794; called by muse, mutect2, varscan2
- CDK19 | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 25/90 reads (28%) | catalogued as COSV60449299; called by muse, mutect2, varscan2
- CFAP47 | c.4390C>G p.P1464A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.29); catalogued as COSV100545731; called by muse, mutect2
- CNNM4 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307384263, COSV100998844; called by muse, mutect2, varscan2
- DCP1A | c.1552G>C p.E518Q | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV99588236; called by muse, mutect2, varscan2
- DTNA | c.2035G>C p.G679R | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs955907160, COSV99315429; called by muse, mutect2, varscan2
- EZHIP | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100539929; called by muse, mutect2, varscan2
- HROB | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs376836214; called by muse, mutect2, varscan2
- HSPA5 | c.123-2A>T p.X41_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100190148; called by muse, mutect2, varscan2
- IL6ST | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.695); catalogued as rs747379809, COSV100411059; called by muse, mutect2, varscan2
- ITPKB | c.2319G>A p.M773I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99685225; called by muse, mutect2, varscan2
- IVL | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV100908274; called by muse, mutect2, varscan2
- JMJD1C | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101232441, COSV101232482; called by muse, mutect2, varscan2
- KBTBD2 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV100406602; called by muse, mutect2, varscan2
- KIAA1549 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs376618613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF21B | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100143256; called by muse, mutect2, varscan2
- KIF2C | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV100946263, COSV64766984; called by muse, mutect2
- KRTAP9-2 | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV100893253; called by muse, mutect2, varscan2
- LHFPL4 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99804972, COSV99805700; called by muse, mutect2, varscan2
- MAP2 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV99561764; called by muse, mutect2, varscan2
- MROH2B | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.167); catalogued as COSV101270673, COSV101270932; called by muse, mutect2, varscan2
- MRPL21 | c.447C>T p.L149= | Splice Region (SNP) | VAF 16/36 reads (44%) | catalogued as rs370223908; called by muse, mutect2, varscan2
- MUC17 | c.5201C>G p.S1734C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100075097; called by muse, mutect2, varscan2
- NBAS | c.2641C>G p.L881V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99871646; called by muse, mutect2, varscan2
- NBEAL1 | c.4392G>A p.W1464* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV101495788; called by muse, mutect2, varscan2
- NFIB | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66620799; called by muse, mutect2
- NHS | c.2547G>T p.K849N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as COSV101197004; called by muse, mutect2, varscan2
- NHS | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101197005; called by muse, mutect2, varscan2
- NOX1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772834730, COSV99471764; called by muse, mutect2, varscan2
- OPLAH | c.974A>C p.Y325S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101470956; called by muse, mutect2, varscan2
- OSBPL9 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100544097; called by muse, mutect2
- OTUD7B | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100967282; called by muse, mutect2
- PAM | c.2216-1G>T p.X739_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | catalogued as COSV99173859; called by muse, mutect2, varscan2
- PARVB | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753954634, COSV58687720; called by muse, mutect2, varscan2
- PCDH19 | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as CM162897, COSV99720810; called by muse, mutect2
- PCDHA8 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs782703557, COSV65325687; called by muse, mutect2, varscan2
- PCDHB3 | c.1970C>A p.T657K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV99166719; called by muse, mutect2, varscan2
- PDPR | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99848901; called by muse, mutect2, varscan2
- PHRF1 | c.4414C>T p.Q1472* (on ENST00000264555 / NM_001286581.2; = p.Q1471* on NM_020901.4) | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99213487; called by muse, mutect2, varscan2
- PLCB4 | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as rs768980104, COSV53807904; called by muse, varscan2
- PTPN21 | c.2554C>T p.L852F | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100162548; called by muse, mutect2, varscan2
- PTPN7 | c.607-1G>T p.X203_splice (on ENST00000495688; = p.X242_splice on NM_002832.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 26/53 reads (49%) | catalogued as COSV100460135; called by muse, mutect2, varscan2
- RAB1B | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs778177996, COSV100268572; called by muse, mutect2, varscan2
- RASGRP1 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.616); catalogued as COSV100172323; called by muse, mutect2, varscan2
- RLBP1 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767805314, COSV99175406; called by muse, mutect2, varscan2
- RPS6KA3 | c.1171A>G p.T391A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV101084667; called by muse, mutect2, varscan2
- SENP6 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as COSV100519574, COSV59194462; called by muse, mutect2, varscan2
- SIPA1L1 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs889311468, COSV100666082; called by muse, mutect2, varscan2
- SYT9 | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100609246; called by muse, mutect2, varscan2
- TASP1 | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100534864, COSV61815635; called by muse, mutect2, varscan2
- TTC22 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199504311, COSV100988186; called by muse, mutect2, varscan2
- TTN | c.18617C>A p.T6206K (on ENST00000591111; = p.T5279K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | PolyPhen benign (0.023); catalogued as COSV60289482; called by muse, mutect2
- TULP4 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV100893847, COSV65579723; called by muse, mutect2, varscan2
- USP54 | c.4099G>A p.G1367S | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100357634; called by muse, mutect2, varscan2
- WDFY3 | c.8524G>A p.D2842N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99885747; called by muse, mutect2, varscan2
- XIRP2 | c.343C>T p.H115Y (on ENST00000628543; = p.H290Y on NM_152381.6) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.074); catalogued as COSV99747594; called by muse, mutect2, varscan2
- ZNF79 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100688287; called by muse, mutect2, varscan2
- ZSCAN25 | c.387G>A p.A129= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as rs771782387, COSV99500746; called by muse, mutect2, varscan2
- ZSWIM8 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.055); catalogued as rs1208999483, COSV67132098; called by muse, mutect2, varscan2
- FMNL3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- GNB5 | c.584C>A p.T195N (on ENST00000261837 / NM_016194.4; = p.T153N on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABHD17A | c.744C>T p.L248= (on ENST00000292577 / NM_001130111.2; = p.L299= on NM_031213.4) | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs1332250270, COSV99171388; called by muse, mutect2, varscan2
- ACTR10 | c.54C>T p.I18= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- AFM | c.1635G>A p.R545= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- BPIFB1 | c.1266G>A p.L422= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99487614; called by muse, mutect2, varscan2
- CACNA2D1 | c.2301C>T p.S767= (on ENST00000356253 / NM_001366867.1; = p.S755= on NM_000722.4) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV100667362; called by muse, mutect2, varscan2
- CANX | c.141A>G p.P47= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs1238535070, COSV99910693; called by muse, mutect2, varscan2
- CDHR3 | c.1830C>T p.N610= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs141106968; called by muse, mutect2, varscan2
- CES3 | c.454C>T p.L152= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100310055; called by muse, mutect2, varscan2
- CNNM4 | c.969C>T p.L323= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100998845, COSV65660179; called by muse, mutect2, varscan2
- FAT4 | c.11658T>C p.F3886= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100630260; called by muse, mutect2, varscan2
- FERMT1 | c.450G>A p.K150= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as rs1457819936, COSV99451285; called by muse, mutect2, varscan2
- GCNA | c.594C>T p.D198= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs757681428, COSV101032715; called by muse, mutect2, varscan2
- GLMP | c.1065C>T p.L355= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99828142; called by muse, mutect2
- GPR139 | c.117C>T p.L39= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs370214126; called by muse, mutect2, varscan2
- IGSF21 | c.945C>T p.N315= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1413947289, COSV99246272; called by muse, mutect2, varscan2
- JUNB | c.900G>A p.V300= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100040358; called by muse, mutect2, varscan2
- LATS2 | c.2859C>T p.C953= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as rs1225518793, COSV101231676, COSV66876459; called by muse, mutect2, varscan2
- MIA3 | c.4554G>A p.Q1518= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs761929438, COSV100485232; called by muse, mutect2, varscan2
- NPBWR1 | c.405C>T p.Y135= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs757810335, COSV100488309; called by muse, mutect2, varscan2
- OR5D18 | c.525C>T p.I175= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100450909; called by muse, mutect2, varscan2
- OR5T1 | c.180G>A p.P60= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs145314711; called by muse, mutect2, varscan2
- OTX2 | c.108G>A p.R36= (on ENST00000408990 / NM_172337.3; = p.R44= on NM_021728.4) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100258103; called by muse, mutect2, varscan2
- PAGR1 | c.456G>A p.P152= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100232669, COSV100232809; called by muse, mutect2, varscan2
- PDE6H | c.207C>T p.F69= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99844064; called by muse, mutect2, varscan2
- PLEKHG4B | c.1431G>A p.Q477= (on ENST00000283426; = p.Q833= on NM_052909.5) | Silent (SNP) | VAF 71/106 reads (67%) | catalogued as COSV99359822; called by muse, mutect2, varscan2
- PRAMEF5 | c.1251G>A p.R417= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs757529548, COSV100871348; called by muse, mutect2, varscan2
- PRKDC | c.9141C>T p.S3047= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100042937; called by muse, mutect2, varscan2
- PRRC2C | c.6447C>T p.V2149= (on ENST00000367742; = p.V2147= on NM_015172.4) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100146094; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.159G>A p.E53= (on ENST00000421990 / NM_001136042.2; = p.E35= on NM_025267.3) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs774216617, COSV100799467; called by muse, mutect2, varscan2
- RAB2A | c.429C>T p.L143= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs370866047; called by muse, mutect2, varscan2
- SCRIB | c.4074G>A p.Q1358= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100254178, COSV57586992; called by muse, mutect2, varscan2
- SIPA1L3 | c.5182C>T p.L1728= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as COSV99730531, COSV99731006; called by muse, mutect2
- ZNF383 | c.1173G>A p.E391= | Silent (SNP) | VAF 12/261 reads (5%) | catalogued as COSV100776798; called by muse, mutect2
- GRIA3 | c.2440-2660G>A | Intron (SNP) | VAF 63/116 reads (54%) | catalogued as rs745394208, COSV99991836; called by muse, mutect2, varscan2
- MACF1 | c.15832-12077T>G | Intron (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099169 C>T | 3'Flank (SNP) | VAF 16/68 reads (24%) | catalogued as rs761223421; called by muse, mutect2, varscan2
